Somatic mutation profile of tumor specimen 0DFMHK from CCDI case PBBRKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.5 years (6,391 days).
Specimen 0DFMHK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8582d62-d63e-4880-964d-ef4203916a31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFMHM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa7555d9-3ae0-475f-bfdf-7442b0459db3

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAX | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 149/482 reads (31%) | catalogued as rs778173104; called by muse, mutect2, varscan2
- TRIM24 | c.1535C>T p.P512L (on ENST00000343526 / NM_015905.3; = p.P478L on NM_003852.4) | Missense Mutation (SNP) | VAF 62/416 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs747683627, COSV58970831; called by muse, mutect2, varscan2
- RLF | c.3373A>G p.K1125E | Missense Mutation (SNP) | VAF 104/626 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SNRPC | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 81/342 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNFSF11 | c.388-3_392del p.X130_splice | Splice Site (DEL) | VAF 53/344 reads (15%) | called by mutect2, pindel, varscan2
- WDFY3 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 51/424 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DMBT1 | c.4884A>C p.S1628= (on ENST00000338354 / NM_001377530.1; = p.S871= on NM_004406.3) | Silent (SNP) | VAF 56/446 reads (13%) | catalogued as rs1268030302; called by muse, mutect2, varscan2
- FAM110D | c.210C>A p.V70= | Silent (SNP) | VAF 82/516 reads (16%) | called by muse, mutect2, varscan2
- SLC39A4 | c.90C>T p.S30= | Silent (SNP) | VAF 198/746 reads (27%) | catalogued as rs1554874155; called by muse, mutect2, varscan2
